Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JA-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell
NOS 807013

Site Buccal mucosa
C06.0
Jan 9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Buccal mucosa

- "Margin of the inferior alveolar nerve":
- . Uninvolved by neoplasia.
- "Level IIB - Right":
- . Absence of neoplastic involvement in two lymph nodes identified (0/2).
- . Skeletal muscle tissue uninvolved by neoplasia.
- "Level IIA - Right":
- . Metastatic squamous cell carcinoma involving 1 of 8 (1/8) lymph nodes identified, without capsular involvement.
- "Level III - Right":
- . Three lymph nodes were dissected, all uninvolved by neoplasia (0/3).
- "Level IB - Right":
- . One lymph node was dissected, uninvolved by neoplasia (0/1).
- "Right inferior alveolar nerve":
- . Uninvolved by neoplasia.
- "Retromolar area and right palatine tonsil":
- . Moderately differentiated squamous cell carcinoma, ulcerated, infiltrating until the muscle skeletal tissue.
- . Lymphatic invasion: present.
- . Perineural invasion: not identified.
- . Surgical margins uninvolved by neoplasia.

Note:

Osseous tissue in decalcification.

Addendum:

- . The neoplasia infiltrates by contiguity the osseous tissue.
- . Osseous tissue margin uninvolved by neoplasia.

Circumference (Circle)	(QUALIFIED)	(DISQUALIFIED)

Source: NCI Genomic Data Commons file 6cb2744c-921d-40f7-8927-70d172beb1aa (TCGA-UF-A7JA.092B76F2-2085-47DE-8C28-CC4E14CF0D5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).